Somatic mutation profile of tumor specimen 0DVZ19 from CCDI case PBCFEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.2 years (90 days).
Specimen 0DVZ19: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9741425b-e141-43e7-b516-4e3c206626ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61dd613f-6e0f-45e7-acf9-d91e3a078723

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH6 | c.8681T>C p.V2894A | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR52E5 | c.25T>A p.F9I | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.311); called by muse, mutect2
- TANC1 | c.3165G>C p.S1055= | Splice Region (SNP) | VAF 39/204 reads (19%) | called by muse, mutect2, varscan2
- CLSTN1 | c.2397C>T p.G799= (on ENST00000377298 / NM_001009566.3; = p.G789= on NM_014944.4) | Silent (SNP) | VAF 36/341 reads (11%) | called by muse, mutect2, varscan2
- EN1 | c.-88C>G | 5'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
